Somatic mutation profile of tumor specimen ALCH-B1K8-TTP1-B (aliquot ALCH-B1K8-TTP1-B-10-0-D-A710-36) from ALCHEMIST case ALCH-B1K8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,194 days).
Specimen ALCH-B1K8-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0a41188-c33e-4da9-a0d6-7dad27c466f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1K8-NB1-A (Blood Derived Normal), aliquot ALCH-B1K8-NB1-A-1-0-D-A710-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eab2a329-6d52-4428-af0b-c9c2d8b899c6

The open-access MAF lists 201 somatic variants for this specimen: 140 protein-altering or splice-affecting, 41 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 41, Nonsense Mutation 13, Intron 12, Splice Site 9, 3'UTR 5, Splice Region 2, RNA 2, Frame Shift Del 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SOS1 | c.697A>T p.N233Y | Missense Mutation (SNP) | VAF 10/168 reads (6%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen possibly damaging (0.671); catalogued as rs1057519963, COSV67673722; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 32/529 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACACB | c.161C>A p.S54* | Nonsense Mutation (SNP) | VAF 18/275 reads (7%) | catalogued as COSV58146192; called by muse, mutect2
- ACSL6 | c.1642G>T p.G548* (on ENST00000379240; = p.G573* on NM_015256.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/123 reads (12%) | catalogued as COSV57296808, COSV99734470; called by muse, mutect2, varscan2
- ADGRB3 | c.210C>G p.Y70* | Nonsense Mutation (SNP) | VAF 28/338 reads (8%) | catalogued as COSV65383020; called by muse, mutect2
- CD163L1 | c.2597G>T p.G866V | Missense Mutation (SNP) | VAF 20/478 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58013847; called by muse, mutect2
- COL5A2 | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 56/550 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV66408152; called by muse, mutect2
- COL6A3 | c.341del p.G114Efs*9 | Frame Shift Del (DEL) | VAF 12/120 reads (10%) | catalogued as COSV55096379; called by mutect2, pindel, varscan2
- CSMD3 | c.6631G>T p.G2211W (on ENST00000297405 / NM_001363185.1; = p.G2107W on NM_052900.3) | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99829416; called by muse, mutect2
- CSMD3 | c.3251C>G p.P1084R (on ENST00000297405 / NM_001363185.1; = p.P980R on NM_052900.3) | Missense Mutation (SNP) | VAF 41/563 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52216406; called by muse, mutect2
- CST9 | c.105G>T p.M35I | Missense Mutation (SNP) | VAF 33/525 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV65402688; called by muse, mutect2
- DLD | c.439-2A>G p.X147_splice | Splice Site (SNP) | VAF 37/320 reads (12%) | catalogued as COSV99227542; called by muse, mutect2, varscan2
- DNAH11 | c.10495C>T p.Q3499* | Nonsense Mutation (SNP) | VAF 20/389 reads (5%) | catalogued as rs867483555; called by muse, mutect2
- DOCK2 | c.3322A>G p.I1108V | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs1273418878; called by muse, mutect2
- EPHA8 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV51262922; called by muse, mutect2, varscan2
- FEV | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 17/233 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs751411997; called by muse, mutect2
- FFAR2 | c.705C>A p.F235L | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99876161; called by muse, mutect2
- FLG | c.11062C>T p.H3688Y | Missense Mutation (SNP) | VAF 17/546 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.607); catalogued as COSV100911972, COSV64240363; called by muse, mutect2
- FPGT-TNNI3K | c.2008A>T p.R670W | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1258835706; called by muse, mutect2, varscan2
- IMMP2L | c.136-1G>T p.X46_splice | Splice Site (SNP) | VAF 30/228 reads (13%) | catalogued as COSV59254796; called by muse, mutect2, varscan2
- KDR | c.3193-1G>A p.X1065_splice | Splice Site (SNP) | VAF 28/483 reads (6%) | catalogued as rs779170295; called by muse, mutect2
- KRTAP4-12 | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs765414181; called by muse, mutect2
- LAMB4 | c.1994C>A p.A665E | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs764574034, COSV52728727; called by muse, mutect2
- LRP1B | c.9815-1G>T p.X3272_splice | Splice Site (SNP) | VAF 10/89 reads (11%) | catalogued as COSV67182961; called by muse, mutect2
- LTBP1 | c.4705G>T p.D1569Y (on ENST00000404816 / NM_206943.4; = p.D1243Y on NM_000627.4) | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV55378807; called by muse, mutect2
- LYST | c.9304G>T p.D3102Y | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101087910; called by muse, mutect2
- MCAM | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773674401; called by muse, mutect2, varscan2
- MGAM2 | c.5026C>A p.P1676T | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs1305332686; called by muse, mutect2
- MUC16 | c.10436G>T p.G3479V | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV67474643; called by muse, mutect2
- NF1 | c.2991-1G>T p.X997_splice | Splice Site (SNP) | VAF 28/338 reads (8%) | catalogued as CS000875, CS1311521, CS961633, COSV62210968; called by muse, mutect2
- OR11H2 | c.511C>G p.P171A (on ENST00000556246; = p.P182A on NM_001197287.1) | Missense Mutation (SNP) | VAF 37/1021 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs1473799114; called by muse, mutect2
- OR4N2 | c.284G>T p.R95I | Missense Mutation (SNP) | VAF 14/410 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.106); catalogued as COSV60051058, COSV60054174; called by muse, mutect2
- PCDHGA10 | c.1599G>T p.Q533H | Missense Mutation (SNP) | VAF 15/351 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.049); catalogued as COSV53926116, COSV53993548; called by muse, mutect2
- PLCB3 | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.773); catalogued as COSV54191779; called by muse, mutect2
- PLSCR5 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101494460; called by muse, mutect2
- PSKH2 | c.498G>T p.M166I | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs1211900544, COSV99404996; called by muse, mutect2
- RBM10 | c.1247A>T p.Q416L | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61308787; called by muse, mutect2
- RUNX1T1 | c.797G>T p.R266L (on ENST00000265814 / NM_001198628.1; = p.R239L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99750353; called by muse, mutect2
- SDS | c.156G>A p.W52* | Nonsense Mutation (SNP) | VAF 21/281 reads (7%) | catalogued as rs768264474; called by muse, mutect2
- SERPINA9 | c.244C>A p.L82I | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV104399698; called by muse, mutect2
- SYNE2 | c.5650C>G p.L1884V | Missense Mutation (SNP) | VAF 19/512 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.245); catalogued as COSV59946665; called by muse, mutect2
- TAFA1 | c.143C>A p.A48E | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV72039898; called by muse, mutect2
- TMEM19 | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 27/553 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs1342604498, COSV57000054; called by muse, mutect2
- TNNI3K | c.2084C>T p.S695L | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV58557246, COSV58559965; called by muse, mutect2
- TRPA1 | c.2706G>T p.L902F | Missense Mutation (SNP) | VAF 34/656 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as rs1384035965; called by muse, mutect2
- USP51 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.714); catalogued as COSV72351766; called by muse, mutect2, varscan2
- VPS13D | c.1325G>A p.G442D | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62524766, COSV62532951; called by muse, mutect2
- ACSBG1 | c.51C>G p.S17R | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- AMBRA1 | c.1819G>T p.E607* (on ENST00000458649 / NM_001367468.1; = p.E517* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- AMFR | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- ANGEL2 | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 21/327 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANKH | c.365A>T p.E122V | Missense Mutation (SNP) | VAF 26/482 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.383); called by muse, mutect2
- ANO6 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 34/568 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.053); called by muse, mutect2
- APLP1 | c.1799C>A p.S600Y (on ENST00000221891 / NM_001024807.3; = p.S599Y on NM_005166.4) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ARSF | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASPM | c.7798A>G p.N2600D | Missense Mutation (SNP) | VAF 20/562 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.306); called by muse, mutect2
- AURKC | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 21/330 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); called by muse, mutect2
- BRAF | c.252A>T p.E84D | Missense Mutation (SNP) | VAF 24/349 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2
- BST2 | c.411G>T p.L137= | Splice Region (SNP) | VAF 10/274 reads (4%) | called by muse, mutect2
- CCDC180 | c.4314G>T p.Q1438H | Missense Mutation (SNP) | VAF 17/237 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.851); called by muse, mutect2
- CCDC61 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCM2 | c.1183A>T p.T395S | Missense Mutation (SNP) | VAF 64/506 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, varscan2
- CLCN2 | c.303G>T p.M101I | Missense Mutation (SNP) | VAF 29/560 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.114); called by muse, mutect2
- CNTNAP5 | c.1044G>C p.K348N | Missense Mutation (SNP) | VAF 9/229 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2
- CRISPLD1 | c.371G>T p.W124L | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2
- CSMD3 | c.401+6T>A | Splice Region (SNP) | VAF 15/139 reads (11%) | called by muse, mutect2, varscan2
- DCAF8L2 | c.1573C>A p.L525I | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCLRE1C | c.1195_1200del p.I399_P400del (on ENST00000378278 / NM_001350965.2; = p.I284_P285del on NM_022487.4) | In Frame Del (DEL) | VAF 17/172 reads (10%) | called by mutect2, pindel, varscan2
- DNAH10 | c.5039C>A p.S1680* (on ENST00000409039; = p.S1619* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 35/588 reads (6%) | called by muse, mutect2
- EML6 | c.869G>T p.C290F | Missense Mutation (SNP) | VAF 19/369 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.439); called by muse, mutect2
- ERICH3 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 16/239 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ESRP1 | c.1453G>T p.G485C | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EYS | c.8380C>G p.L2794V (on ENST00000370621 / NM_001292009.1; = p.L2773V on NM_001142800.2) | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2
- EYS | c.2590T>A p.S864T | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); called by muse, mutect2
- FAR2 | c.1332C>A p.Y444* | Nonsense Mutation (SNP) | VAF 25/420 reads (6%) | called by muse, mutect2
- GDA | c.161T>A p.L54Q | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); called by muse, mutect2
- GTF2F1 | c.1032G>T p.E344D | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GYPC | c.363C>A p.S121R | Missense Mutation (SNP) | VAF 32/447 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.361); called by muse, mutect2
- HAPLN1 | c.29T>C p.I10T | Missense Mutation (SNP) | VAF 28/359 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- HELB | c.1009T>C p.F337L | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IVL | c.1580A>T p.E527V | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2
- JAG2 | c.290T>A p.V97E | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- JMY | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- KDM7A | c.1052-1G>T p.X351_splice | Splice Site (SNP) | VAF 24/354 reads (7%) | called by muse, mutect2
- LAMC3 | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- LHFPL5 | c.470T>A p.V157E | Missense Mutation (SNP) | VAF 21/312 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LILRA2 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LMLN | c.929+1G>T p.X310_splice | Splice Site (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- LRRC53 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- LRRK2 | c.1362T>G p.H454Q | Missense Mutation (SNP) | VAF 23/316 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2
- MAGEC1 | c.2607A>T p.E869D | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- MAK | c.1540T>C p.F514L | Missense Mutation (SNP) | VAF 52/656 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- MFSD9 | c.254-2A>T p.X85_splice | Splice Site (SNP) | VAF 12/302 reads (4%) | called by muse, mutect2
- MIOS | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 34/339 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MKNK1 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- MROH9 | c.1279C>A p.L427I | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- NKX2-1 | c.862C>G p.Q288E | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- OR52L1 | c.428C>A p.A143D | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR6C3 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- P2RY8 | c.266G>T p.W89L | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDH9 | c.543G>T p.L181F | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB3 | c.1008G>T p.Q336H | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PCLO | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 34/504 reads (7%) | called by muse, mutect2
- PHF2 | c.910A>T p.K304* | Nonsense Mutation (SNP) | VAF 9/168 reads (5%) | called by muse, mutect2
- PHLPP2 | c.2647G>T p.D883Y | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); called by muse, mutect2
- POTEA | c.398G>T p.R133M | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2
- PPP1R16B | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRAMEF20 | c.1321G>T p.V441L | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.109); called by muse, mutect2
- PRKAR1A | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2
- PROSER1 | c.1673A>T p.Q558L | Missense Mutation (SNP) | VAF 28/319 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.157); called by muse, mutect2
- PSD3 | c.2176-2A>T p.X726_splice (on ENST00000440756; = p.X725_splice on NM_015310.4) | Splice Site (SNP) | VAF 18/382 reads (5%) | called by muse, mutect2
- PTPN4 | c.2214G>C p.W738C | Missense Mutation (SNP) | VAF 22/437 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAPGEF6 | c.1131G>T p.W377C | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2
- RASGEF1A | c.779C>A p.T260N | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- RFX3 | c.1732A>G p.M578V | Missense Mutation (SNP) | VAF 19/484 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- SELENOP | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); called by muse, mutect2
- SEPTIN5 | c.914A>T p.E305V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SGIP1 | c.110C>A p.P37Q | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.146); called by muse, mutect2
- SGIP1 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2
- SIGLEC1 | c.602C>A p.T201N | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); called by muse, mutect2
- SLC28A1 | c.982C>A p.P328T | Missense Mutation (SNP) | VAF 26/531 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC28A1 | c.983C>A p.P328H | Missense Mutation (SNP) | VAF 27/535 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STK36 | c.2914C>A p.H972N | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- STYXL2 | c.3377G>C p.R1126T | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2
- STYXL2 | c.3378G>T p.R1126S | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2
- SYVN1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TAF15 | c.1132C>T p.Q378* (on ENST00000605844 / NM_139215.3; = p.Q375* on NM_003487.4) | Nonsense Mutation (SNP) | VAF 20/579 reads (3%) | called by muse, mutect2
- TARS3 | c.1561A>T p.R521* | Nonsense Mutation (SNP) | VAF 11/271 reads (4%) | called by muse, mutect2
- TBC1D9B | c.522G>T p.W174C | Missense Mutation (SNP) | VAF 16/273 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- THBS2 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, varscan2
- TMEFF2 | c.452C>A p.S151Y | Missense Mutation (SNP) | VAF 34/397 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM232 | c.1792C>A p.H598N | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.179); called by muse, mutect2
- TNFAIP2 | c.1051A>T p.R351W | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2
- USO1 | c.2357A>T p.Q786L | Missense Mutation (SNP) | VAF 20/299 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- VCAN | c.9894G>T p.Q3298H | Missense Mutation (SNP) | VAF 18/367 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VGLL3 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); called by muse, mutect2
- WNK2 | c.3884A>T p.Q1295L | Missense Mutation (SNP) | VAF 23/370 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2
- ZNF577 | c.46A>C p.S16R | Missense Mutation (SNP) | VAF 31/447 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.169); called by muse, mutect2
- ZNF831 | c.4889C>A p.S1630Y | Missense Mutation (SNP) | VAF 30/419 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2
- ZRANB3 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.802); called by muse, mutect2
- AASS | c.1962A>T p.P654= | Silent (SNP) | VAF 38/401 reads (9%) | called by muse, mutect2
- ADAMTS19 | c.3126C>T p.C1042= | Silent (SNP) | VAF 11/289 reads (4%) | called by muse, mutect2
- ADH4 | c.948C>A p.I316= | Silent (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- AGGF1 | c.1266A>T p.I422= | Silent (SNP) | VAF 24/344 reads (7%) | called by muse, mutect2
- AMBRA1 | c.1818T>C p.F606= (on ENST00000458649 / NM_001367468.1; = p.F516= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 12/268 reads (4%) | called by muse, mutect2
- C2orf66 | c.51G>T p.G17= | Silent (SNP) | VAF 12/228 reads (5%) | called by muse, mutect2
- CDRT15 | c.510C>A p.V170= | Silent (SNP) | VAF 12/308 reads (4%) | catalogued as COSV69755650; called by muse, mutect2
- CHIC1 | c.348G>A p.G116= | Silent (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- DNAI4 | c.1263A>T p.A421= | Silent (SNP) | VAF 28/380 reads (7%) | catalogued as COSV64023902; called by muse, mutect2
- FAM234A | c.306G>T p.G102= | Silent (SNP) | VAF 12/203 reads (6%) | called by muse, mutect2
- FAM53C | c.588G>T p.L196= | Silent (SNP) | VAF 35/502 reads (7%) | called by muse, mutect2
- GFM1 | c.1998A>T p.A666= | Silent (SNP) | VAF 38/392 reads (10%) | catalogued as rs765400655, COSV99962910; called by muse, mutect2
- HECW1 | c.2025G>A p.A675= | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- IL20 | c.33C>A p.L11= | Silent (SNP) | VAF 18/261 reads (7%) | catalogued as COSV65584699; called by muse, mutect2
- KCNC1 | c.456C>A p.T152= | Silent (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- LCOR | c.4575A>T p.S1525= | Silent (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- LRP1B | c.7140A>G p.S2380= | Silent (SNP) | VAF 28/356 reads (8%) | catalogued as rs1199832389; called by muse, mutect2
- MYEF2 | c.1005G>T p.G335= | Silent (SNP) | VAF 12/250 reads (5%) | called by muse, mutect2
- NEK1 | c.3096G>T p.L1032= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- OR52R1 | c.750C>A p.V250= | Silent (SNP) | VAF 16/301 reads (5%) | catalogued as COSV61889075; called by muse, mutect2
- OR5J2 | c.387C>T p.P129= | Silent (SNP) | VAF 21/260 reads (8%) | called by muse, mutect2
- OR6K3 | c.306C>A p.I102= (on ENST00000368146; = p.I86= on NM_001005327.2) | Silent (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- PCDHA5 | c.1479G>T p.L493= | Silent (SNP) | VAF 23/345 reads (7%) | catalogued as rs61730630; called by muse, mutect2
- PCDHB11 | c.1452C>A p.A484= | Silent (SNP) | VAF 17/418 reads (4%) | called by muse, mutect2
- PLEKHG3 | c.1245G>T p.G415= (on ENST00000394691; = p.G471= on NM_001308147.2) | Silent (SNP) | VAF 9/157 reads (6%) | called by muse, mutect2
- PNRC1 | c.198G>T p.P66= | Silent (SNP) | VAF 12/174 reads (7%) | catalogued as COSV60139470; called by muse, mutect2
- PRPF31 | c.1158C>T p.D386= | Silent (SNP) | VAF 20/230 reads (9%) | catalogued as rs147295591; called by muse, mutect2
- RELN | c.5889T>C p.F1963= | Silent (SNP) | VAF 46/464 reads (10%) | catalogued as rs770277133; called by muse, mutect2, varscan2
- RUNX2 | c.1377G>A p.V459= (on ENST00000371438; = p.V437= on NM_001015051.3) | Silent (SNP) | VAF 16/498 reads (3%) | called by muse, mutect2
- RYR2 | c.5340A>G p.P1780= | Silent (SNP) | VAF 32/512 reads (6%) | catalogued as rs749662039; called by muse, mutect2
- SMAD2 | c.84A>T p.A28= | Silent (SNP) | VAF 18/400 reads (5%) | called by muse, mutect2
- TAAR8 | c.375C>T p.I125= | Silent (SNP) | VAF 17/242 reads (7%) | called by muse, mutect2
- TNR | c.1893G>T p.L631= | Silent (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- TNXB | c.10320C>T p.F3440= (on ENST00000647633; = p.F3193= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/358 reads (4%) | catalogued as rs773892921, COSV64476863; called by muse, mutect2
- UMOD | c.153C>T p.T51= | Silent (SNP) | VAF 22/282 reads (8%) | catalogued as COSV100208027; called by muse, mutect2
- URGCP | c.828C>G p.S276= (on ENST00000453200 / NM_001077663.3; = p.S267= on NM_017920.4) | Silent (SNP) | VAF 16/298 reads (5%) | catalogued as COSV56251808; called by muse, mutect2
- USP44 | c.916C>T p.L306= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- VSIG4 | c.60T>C p.R20= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as rs981529502; called by mutect2, varscan2
- VWDE | c.2790G>T p.G930= | Silent (SNP) | VAF 18/160 reads (11%) | called by muse, mutect2, varscan2
- ZNF484 | c.387A>T p.G129= | Silent (SNP) | VAF 17/278 reads (6%) | called by muse, mutect2
- ZNF862 | c.2397G>T p.A799= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV99783876; called by muse, mutect2, varscan2
- ABCC8 | c.3868-15G>T | Intron (SNP) | VAF 9/258 reads (3%) | called by muse, mutect2
- ARMC8 | c.1822-10G>A | Intron (SNP) | VAF 18/216 reads (8%) | called by muse, mutect2
- CXCL12 | c.266+958G>A | Intron (SNP) | VAF 14/232 reads (6%) | catalogued as rs1031293947; called by muse, mutect2
- EYS | c.1767-6810C>A | Intron (SNP) | VAF 38/651 reads (6%) | called by muse, mutect2
- FBN2 | c.952+39C>A | Intron (SNP) | VAF 14/198 reads (7%) | called by muse, mutect2
- HBS1L | c.430+1679A>T | Intron (SNP) | VAF 15/133 reads (11%) | catalogued as rs941032816; called by muse, mutect2, varscan2
- HOXA11 | chr7:27180130 C>A | 3'Flank (SNP) | VAF 6/76 reads (8%) | catalogued as rs979301828; called by muse, mutect2
- KYNU | c.902+2845G>A | Intron (SNP) | VAF 18/414 reads (4%) | called by muse, mutect2
- NPIPB1P | n.224C>G | RNA (SNP) | VAF 22/270 reads (8%) | called by muse, mutect2
- OR7E5P | n.541G>T | RNA (SNP) | VAF 25/573 reads (4%) | called by muse, mutect2
- PDCD10 | c.*48G>T | 3'UTR (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- PDLIM5 | c.96+1049G>T | Intron (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- PLCH2 | c.2959+521C>T | Intron (SNP) | VAF 11/226 reads (5%) | catalogued as rs965565985; called by muse, mutect2
- RGS6 | c.*228G>C | 3'UTR (SNP) | VAF 14/264 reads (5%) | called by muse, mutect2
- SMARCE1 | c.237+12G>A | Intron (SNP) | VAF 34/432 reads (8%) | called by muse, mutect2
- STIL | c.45-45G>T | Intron (SNP) | VAF 11/231 reads (5%) | called by muse, mutect2
- TMCO1 | c.*2582C>T | 3'UTR (SNP) | VAF 18/328 reads (5%) | called by muse, mutect2
- TMEM135 | c.*3114G>T | 3'UTR (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- TSHZ2 | c.*1975A>T | 3'UTR (SNP) | VAF 46/712 reads (6%) | called by muse, mutect2
- UNC79 | c.3754+1532A>T | Intron (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
